Somatic mutation profile of tumor specimen TCGA-BA-A4IF-01A (aliquot TCGA-BA-A4IF-01A-11D-A25Y-08) from TCGA case TCGA-BA-A4IF, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, keratinizing, NOS; Tissue or organ of origin: Posterior wall of oropharynx; Tumor grade: G2; Age at diagnosis: 59.2 years (21,635 days).
Specimen TCGA-BA-A4IF-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1d4da49b-7f86-4ee6-b0d0-5192758d0632.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BA-A4IF-10A (Blood Derived Normal), aliquot TCGA-BA-A4IF-10A-01D-A25Y-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c9bcf459-6867-4617-9879-3ab3555c2fe7

The open-access MAF lists 100 somatic variants for this specimen: 81 protein-altering or splice-affecting, 19 silent.
By variant classification: Missense Mutation 68, Silent 19, Nonsense Mutation 5, Frame Shift Del 3, Frame Shift Ins 2, Splice Site 1, In Frame Del 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDKN2A | c.262G>T p.E88* | Nonsense Mutation (SNP) | VAF 20/45 reads (44%) | hotspot (GDC flag); catalogued as rs121913384, CM034218, CM095540, COSV58683071, COSV58683670; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.1633G>A p.E545K | Missense Mutation (SNP) | VAF 30/56 reads (54%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.909); catalogued as rs104886003, CM126692, COSV55873239, COSV55878227; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, varscan2
- TP53 | c.400T>G p.F134V | Missense Mutation (SNP) | VAF 37/73 reads (51%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52660909, COSV52676112, COSV52697695, COSV52923862; called by muse, mutect2, varscan2
- AGAP3 | c.935G>A p.R312Q (on ENST00000622464; = p.R348Q on NM_031946.7 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 25/113 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.164); catalogued as rs752599574, COSV100103904, COSV58996642; called by muse, mutect2, varscan2
- AKAP9 | c.4030G>C p.E1344Q | Missense Mutation (SNP) | VAF 17/49 reads (35%) | SIFT tolerated (0.1); PolyPhen benign (0.037); catalogued as COSV100662430; called by muse, mutect2, varscan2
- ALDH1B1 | c.542A>G p.Q181R | Missense Mutation (SNP) | VAF 40/119 reads (34%) | SIFT deleterious (0.01); PolyPhen benign (0.046); catalogued as COSV100890946; called by muse, mutect2, varscan2
- AMPH | c.1999G>A p.G667R | Missense Mutation (SNP) | VAF 18/101 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100342210; called by muse, mutect2, varscan2
- ASTN2 | c.3563C>T p.T1188M (on ENST00000313400 / NM_001365069.1; = p.T1137M on NM_014010.5) | Missense Mutation (SNP) | VAF 18/138 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.429); catalogued as rs762408231, COSV56004007; called by muse, mutect2, varscan2
- AURKA | c.291G>T p.K97N | Missense Mutation (SNP) | VAF 24/270 reads (9%) | SIFT tolerated (0.22); PolyPhen benign (0.015); catalogued as COSV100453020; called by muse, mutect2
- AURKC | c.102C>A p.A34= | Splice Region (SNP) | VAF 10/134 reads (7%) | catalogued as COSV100248870; called by muse, mutect2
- BCL2A1 | c.467C>T p.T156I | Missense Mutation (SNP) | VAF 16/49 reads (33%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as COSV99144336; called by muse, mutect2, varscan2
- CHST5 | c.508G>A p.V170I | Missense Mutation (SNP) | VAF 93/425 reads (22%) | SIFT tolerated (0.27); PolyPhen benign (0.227); catalogued as rs372806195, COSV100291957; called by muse, mutect2, varscan2
- CLDN22 | c.309C>G p.D103E | Missense Mutation (SNP) | VAF 10/56 reads (18%) | SIFT tolerated (0.68); PolyPhen possibly damaging (0.605); catalogued as COSV100032908; called by muse, mutect2, varscan2
- CMIP | c.1733G>C p.R578T (on ENST00000537098 / NM_198390.2; = p.R484T on NM_030629.3) | Missense Mutation (SNP) | VAF 9/50 reads (18%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.942); catalogued as COSV101220909; called by muse, mutect2, varscan2
- CSGALNACT1 | c.98C>T p.A33V | Missense Mutation (SNP) | VAF 38/124 reads (31%) | SIFT tolerated (0.17); PolyPhen benign (0.284); catalogued as COSV100175030; called by muse, mutect2, varscan2
- CYB5R3 | c.428G>A p.R143Q | Missense Mutation (SNP) | VAF 16/246 reads (7%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.611); catalogued as rs370695594; called by muse, mutect2
- DNAJC25 | c.578A>T p.K193M | Missense Mutation (SNP) | VAF 8/39 reads (21%) | SIFT tolerated (0.07); PolyPhen benign (0.238); catalogued as COSV100543374; called by muse, mutect2, varscan2
- DST | c.2414C>T p.T805I (on ENST00000361203 / NM_001374722.1; = p.T479I on NM_001723.6) | Missense Mutation (SNP) | VAF 28/106 reads (26%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as rs1270252749, COSV99756330; called by muse, mutect2, varscan2
- EPB41L5 | c.884A>C p.Q295P | Missense Mutation (SNP) | VAF 8/116 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99758754; called by muse, mutect2
- F13A1 | c.1639del p.R547Vfs*30 | Frame Shift Del (DEL) | VAF 23/117 reads (20%) | catalogued as COSV53553578, COSV99343451; called by mutect2, pindel, varscan2
- FAM117A | c.1214C>T p.P405L | Missense Mutation (SNP) | VAF 20/84 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as rs138923537, COSV53604130; called by muse, mutect2, varscan2
- FAT1 | c.2809C>T p.R937* | Nonsense Mutation (SNP) | VAF 116/300 reads (39%) | catalogued as rs547340067, COSV71672032; called by muse, mutect2, varscan2
- FAT2 | c.11089C>T p.Q3697* | Nonsense Mutation (SNP) | VAF 60/111 reads (54%) | catalogued as COSV99942959; called by muse, mutect2, varscan2
- GOLGA4 | c.2272A>G p.I758V | Missense Mutation (SNP) | VAF 13/80 reads (16%) | SIFT tolerated (0.26); PolyPhen benign (0.003); catalogued as COSV100728918; called by muse, mutect2, varscan2
- GPT2 | c.983C>A p.S328Y | Missense Mutation (SNP) | VAF 42/210 reads (20%) | SIFT tolerated (0.13); PolyPhen benign (0.249); catalogued as COSV100412936; called by muse, mutect2, varscan2
- GRIN2B | c.1758C>A p.N586K | Missense Mutation (SNP) | VAF 45/189 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV101663051; called by muse, mutect2, varscan2
- H3-4 | c.206A>T p.Q69L | Missense Mutation (SNP) | VAF 73/251 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.995); catalogued as COSV100797389; called by muse, mutect2, varscan2
- HDAC10 | c.1952G>C p.R651T | Missense Mutation (SNP) | VAF 4/48 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.711); catalogued as COSV99352362; called by muse, mutect2
- HECW2 | c.259G>T p.D87Y | Missense Mutation (SNP) | VAF 8/83 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53650614, COSV99647283; called by muse, mutect2
- HNRNPD | c.586G>C p.E196Q | Missense Mutation (SNP) | VAF 36/94 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.588); catalogued as COSV100002926; called by muse, mutect2, varscan2
- HSPB3 | c.127G>T p.V43L | Missense Mutation (SNP) | VAF 8/90 reads (9%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as COSV100115939; called by muse, mutect2
- IMPG2 | c.1865A>G p.E622G | Missense Mutation (SNP) | VAF 20/230 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.541); catalogued as COSV99515624; called by muse, mutect2
- INTS6 | c.1703G>T p.R568L | Missense Mutation (SNP) | VAF 19/67 reads (28%) | SIFT tolerated (0.66); PolyPhen benign (0.001); catalogued as COSV100247084; called by muse, mutect2, varscan2
- KIAA0232 | c.1346G>C p.C449S | Missense Mutation (SNP) | VAF 23/71 reads (32%) | SIFT tolerated (0.14); PolyPhen benign (0.167); catalogued as COSV100300730; called by muse, mutect2, varscan2
- KIAA0513 | c.1222A>G p.M408V | Missense Mutation (SNP) | VAF 17/95 reads (18%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.914); catalogued as rs888927602, COSV99260898; called by muse, mutect2, varscan2
- KLHL22 | c.1091G>T p.R364L | Missense Mutation (SNP) | VAF 37/157 reads (24%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.767); catalogued as rs552098595, COSV100186039; called by muse, mutect2, varscan2
- KRTAP13-4 | c.200G>A p.R67H | Missense Mutation (SNP) | VAF 18/114 reads (16%) | SIFT tolerated (0.37); PolyPhen benign (0.027); catalogued as rs139497735, COSV61878675; called by muse, mutect2, varscan2
- LDLRAP1 | c.414C>A p.N138K | Missense Mutation (SNP) | VAF 33/124 reads (27%) | SIFT deleterious (0); PolyPhen benign (0.289); catalogued as COSV100974755; called by muse, mutect2, varscan2
- LRP6 | c.4786A>G p.S1596G | Missense Mutation (SNP) | VAF 6/93 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.101); catalogued as COSV99743410; called by muse, mutect2
- MAP1B | c.2590G>A p.E864K | Missense Mutation (SNP) | VAF 136/273 reads (50%) | SIFT deleterious (0.01); PolyPhen benign (0.035); catalogued as rs756153336, COSV57098133; called by muse, mutect2, varscan2
- MCM3 | c.1523C>G p.S508* (on ENST00000229854 / NM_001366374.2; = p.S498* on NM_002388.6 and 5 other RefSeq transcripts) | Nonsense Mutation (SNP) | VAF 35/139 reads (25%) | catalogued as COSV100008845; called by muse, mutect2, varscan2
- MME | c.67C>T p.R23* | Nonsense Mutation (SNP) | VAF 24/248 reads (10%) | catalogued as rs150836510; called by muse, mutect2
- MSC | c.157G>A p.D53N | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.055); catalogued as rs529973134, COSV100335745, COSV57697289; called by muse, mutect2, varscan2
- MTUS2 | c.2139G>T p.L713F | Missense Mutation (SNP) | VAF 26/90 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV101462239, COSV70919354; called by muse, mutect2, varscan2
- MUC16 | c.35552C>A p.S11851Y | Missense Mutation (SNP) | VAF 58/132 reads (44%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.961); catalogued as COSV101200010, COSV67460149; called by muse, mutect2, varscan2
- MUC16 | c.27985A>G p.S9329G | Missense Mutation (SNP) | VAF 67/204 reads (33%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.042); catalogued as COSV101200011; called by muse, mutect2, varscan2
- MYH1 | c.3578C>T p.A1193V | Missense Mutation (SNP) | VAF 27/181 reads (15%) | SIFT tolerated (0.12); PolyPhen benign (0.007); catalogued as rs563239651, COSV56843341; called by muse, mutect2, varscan2
- NFATC2 | c.1654G>C p.E552Q | Missense Mutation (SNP) | VAF 23/106 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.257); catalogued as COSV101044144; called by muse, mutect2, varscan2
- NOTCH1 | c.6180+1G>C p.X2060_splice | Splice Site (SNP) | VAF 38/177 reads (21%) | catalogued as COSV53055461, COSV99488237; called by muse, mutect2, varscan2
- NR4A2 | c.128G>A p.S43N | Missense Mutation (SNP) | VAF 35/95 reads (37%) | SIFT tolerated (0.15); PolyPhen benign (0.015); catalogued as COSV100277200; called by muse, mutect2, varscan2
- NRXN1 | c.277T>A p.F93I | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.059); catalogued as COSV68015080; called by muse, mutect2
- NRXN3 | c.26G>T p.R9L | Missense Mutation (SNP) | VAF 66/274 reads (24%) | SIFT tolerated, low confidence (0.65); PolyPhen benign (0); catalogued as COSV99819012, COSV99821792; called by muse, mutect2, varscan2
- NSD1 | c.4994C>T p.P1665L | Missense Mutation (SNP) | VAF 69/146 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100729151; called by muse, mutect2, varscan2
- OR51G2 | c.688G>A p.V230M | Missense Mutation (SNP) | VAF 17/83 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs185474285, COSV58992480; called by muse, mutect2, varscan2
- PBLD | c.731A>T p.H244L | Missense Mutation (SNP) | VAF 35/176 reads (20%) | SIFT tolerated (0.1); PolyPhen benign (0); catalogued as COSV99516117; called by muse, mutect2, varscan2
- PCDHB16 | c.1966G>A p.A656T | Missense Mutation (SNP) | VAF 81/171 reads (47%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.003); catalogued as COSV53359761; called by muse, mutect2, varscan2
- PRKCG | c.160G>T p.D54Y | Missense Mutation (SNP) | VAF 21/93 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV99669037; called by muse, mutect2, varscan2
- QARS1 | c.1394C>G p.S465C | Missense Mutation (SNP) | VAF 7/75 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100070049; called by muse, mutect2
- RWDD2A | c.742G>C p.E248Q | Missense Mutation (SNP) | VAF 16/115 reads (14%) | SIFT tolerated (0.78); PolyPhen benign (0.039); catalogued as COSV99392382; called by muse, mutect2, varscan2
- SLC5A7 | c.260C>T p.A87V | Missense Mutation (SNP) | VAF 13/71 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.585); catalogued as rs1558859918, COSV99886694; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SLCO5A1 | c.662C>T p.P221L | Missense Mutation (SNP) | VAF 19/51 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as rs762870502, COSV99480094, COSV99480242; called by muse, mutect2, varscan2
- SORCS1 | c.2341G>A p.V781I | Missense Mutation (SNP) | VAF 29/132 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.241); catalogued as rs370679881, COSV53857213; called by muse, mutect2, varscan2
- SSTR5 | c.851G>A p.G284D | Missense Mutation (SNP) | VAF 33/115 reads (29%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.6); catalogued as COSV99559724; called by muse, mutect2, varscan2
- SSX2IP | c.1649G>T p.R550L | Missense Mutation (SNP) | VAF 32/190 reads (17%) | SIFT tolerated (0.79); PolyPhen benign (0.011); catalogued as COSV100642594; called by muse, mutect2, varscan2
- TGFBRAP1 | c.2578A>T p.T860S | Missense Mutation (SNP) | VAF 20/110 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.985); catalogued as COSV99305131; called by muse, mutect2, varscan2
- TMEM72 | c.481G>A p.G161S | Missense Mutation (SNP) | VAF 70/298 reads (23%) | SIFT tolerated (0.82); PolyPhen possibly damaging (0.854); catalogued as rs201160000; called by muse, mutect2, varscan2
- TRIM58 | c.1226G>T p.R409L | Missense Mutation (SNP) | VAF 57/196 reads (29%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.545); catalogued as rs571276238, COSV63569824, COSV63571059; called by muse, mutect2, varscan2
- TSPAN31 | c.166C>T p.L56F | Missense Mutation (SNP) | VAF 16/117 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1183521792, COSV99223257; called by muse, mutect2, varscan2
- VPS13D | c.1410C>G p.I470M | Missense Mutation (SNP) | VAF 32/205 reads (16%) | SIFT tolerated (0.09); PolyPhen benign (0.05); catalogued as COSV100693097; called by muse, mutect2, varscan2
- WARS2 | c.742G>T p.V248L | Missense Mutation (SNP) | VAF 39/148 reads (26%) | SIFT tolerated (0.62); PolyPhen benign (0.021); catalogued as COSV99346392; called by muse, mutect2, varscan2
- ZNF211 | c.1201G>A p.E401K (on ENST00000347302 / NM_198855.4; = p.E414K on NM_006385.5) | Missense Mutation (SNP) | VAF 11/85 reads (13%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.89); catalogued as COSV99560294; called by muse, mutect2, varscan2
- ZNF594 | c.1787A>G p.Y596C | Missense Mutation (SNP) | VAF 22/238 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV101280493; called by muse, mutect2
- ZNF785 | c.1102A>T p.R368W | Missense Mutation (SNP) | VAF 39/145 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.86); catalogued as COSV101235695; called by muse, mutect2, varscan2
- ZNF823 | c.422G>A p.R141H (on ENST00000341191 / NM_001297610.2; = p.R97H on NM_017507.2) | Missense Mutation (SNP) | VAF 24/175 reads (14%) | SIFT tolerated (0.08); PolyPhen benign (0.245); catalogued as rs753155696, COSV57873690; called by muse, mutect2, varscan2
- ZNF839 | c.1318G>C p.E440Q (on ENST00000558850 / NM_001267827.1; = p.E556Q on NM_018335.5) | Missense Mutation (SNP) | VAF 13/50 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.964); catalogued as COSV99216258; called by muse, mutect2, varscan2
- AP5Z1 | c.1660del p.Q554Rfs*14 | Frame Shift Del (DEL) | VAF 18/82 reads (22%) | called by mutect2, pindel, varscan2
- IGSF21 | c.971A>T p.K324M | Missense Mutation (SNP) | VAF 11/127 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.907); called by muse, mutect2
- P2RX4 | c.1082dup p.M361Ifs*13 | Frame Shift Ins (INS) | VAF 115/423 reads (27%) | called by mutect2, pindel, varscan2
- RPF2 | c.460_461del p.E154Rfs*3 | Frame Shift Del (DEL) | VAF 5/59 reads (8%) | called by mutect2, pindel
- TANC2 | c.886_894del p.M297_R299del | In Frame Del (DEL) | VAF 7/49 reads (14%) | called by mutect2, pindel, varscan2
- TCHP | c.718dup p.E240Gfs*40 | Frame Shift Ins (INS) | VAF 4/23 reads (17%) | called by mutect2, varscan2
- ACAD11 | c.132G>A p.L44= | Silent (SNP) | VAF 15/102 reads (15%) | catalogued as COSV99392083; called by muse, mutect2, varscan2
- ADAMTS1 | c.2619T>C p.G873= | Silent (SNP) | VAF 18/139 reads (13%) | catalogued as COSV99536162; called by muse, mutect2, varscan2
- ANKRD1 | c.828G>A p.A276= | Silent (SNP) | VAF 7/66 reads (11%) | catalogued as rs758904122, COSV100865338; called by muse, mutect2, varscan2
- DDR1 | c.2631G>A p.P877= (on ENST00000324771; = p.P840= on NM_001954.4) | Silent (SNP) | VAF 36/199 reads (18%) | catalogued as rs371228785, COSV100241567; called by muse, mutect2, varscan2
- EML1 | c.1869A>T p.T623= | Silent (SNP) | VAF 14/106 reads (13%) | catalogued as COSV99215060; called by muse, mutect2, varscan2
- EML2 | c.1644G>A p.R548= | Silent (SNP) | VAF 36/222 reads (16%) | catalogued as rs1273465839, COSV99840049; called by muse, mutect2, varscan2
- FRMPD2 | c.2298A>T p.I766= | Silent (SNP) | VAF 26/102 reads (25%) | catalogued as COSV100563845; called by muse, mutect2, varscan2
- KMT2C | c.9420A>G p.E3140= | Silent (SNP) | VAF 4/20 reads (20%) | catalogued as COSV100072190; called by muse, mutect2
- MTO1 | c.1320G>A p.E440= (on ENST00000370300 / NM_133645.3; = p.E415= on NM_012123.4) | Silent (SNP) | VAF 19/61 reads (31%) | catalogued as COSV100940439; called by muse, mutect2, varscan2
- MUC16 | c.27984T>A p.S9328= | Silent (SNP) | VAF 69/207 reads (33%) | catalogued as COSV101200012; called by muse, mutect2, varscan2
- NBEAL1 | c.5895C>T p.L1965= | Silent (SNP) | VAF 64/149 reads (43%) | catalogued as COSV101355514; called by muse, mutect2, varscan2
- NELFA | c.1620G>A p.*540= (on ENST00000542778; = p.*529= on NM_005663.5) | Silent (SNP) | VAF 10/116 reads (9%) | catalogued as COSV100373357; called by muse, mutect2
- PCDHB8 | c.687C>G p.V229= | Silent (SNP) | VAF 97/428 reads (23%) | catalogued as COSV50803383, COSV99176979; called by muse, mutect2, varscan2
- PPAN-P2RY11 | c.1498C>T p.L500= | Silent (SNP) | VAF 6/36 reads (17%) | catalogued as rs751316316, COSV99461330; called by muse, mutect2, varscan2
- RWDD3 | c.276G>A p.E92= | Silent (SNP) | VAF 23/93 reads (25%) | catalogued as COSV99811596; called by muse, mutect2, varscan2
- SLIT1 | c.3918C>T p.N1306= | Silent (SNP) | VAF 74/334 reads (22%) | catalogued as rs148583876; called by muse, mutect2, varscan2
- TMED6 | c.81A>T p.L27= | Silent (SNP) | VAF 55/225 reads (24%) | catalogued as COSV99651496; called by muse, mutect2, varscan2
- TP53I11 | c.432C>T p.F144= | Silent (SNP) | VAF 6/71 reads (8%) | catalogued as COSV100370897, COSV57534315; called by muse, mutect2
- TRIM7 | c.645G>A p.K215= | Silent (SNP) | VAF 52/111 reads (47%) | catalogued as rs749975908, COSV99220223; called by muse, mutect2, varscan2
